Gene-level copy-number profile of tumor specimen TCGA-49-AARE-01A from TCGA case TCGA-49-AARE, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 51.7 years (18,893 days).
Specimen TCGA-49-AARE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.0706a750-7884-4447-8453-009495f8ace3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-49-AARE-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a582361a-f387-4b65-a844-49a36639bbef

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 1,756; copy number 2: 22,961; copy number 3: 19,290; copy number 4: 12,818; copy number 5: 1,245; copy number 6: 1,187; copy number 7: 112; copy number 8: 322; copy number 10: 28; copy number 12: 15; copy number 13: 8; copy number 15: 30; copy number 17: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-49-AARE-01A-11D-A40Z-01): tumor purity 0.42, ploidy 2.78, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:10,068,089–10,268,231, 11 genes: AC005674.1, WDR1, MIR3138, RNA5SP155, AC093664.1, AC006499.6, AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,947 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:10,120,698–10,211,725, 3 genes, copy number 6: RRM2, AC007240.1, MIR4261.
- chr2:24,199,839–24,413,292, 7 genes, copy number 10: AC008073.1, ITSN2, AC009228.1, AC009228.2, HMGN2P20, RPL36AP13, AC093798.1.
- chr4:25,472,517–25,623,601, 5 genes, copy number 10: AC133963.2, AC133963.1, AC105290.1, RNU7-126P, AC092436.1.
- chr5:12,297,399–17,306,960, 61 genes, copy number 10–17 (broad region; genes not listed).
- chr5:33,502,072–40,860,175, 125 genes, copy number 5 (broad region; genes not listed).
- chr7:70,972–6,826,770, 166 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:16,695,871–17,346,152, 11 genes, copy number 6 (within-gene range 4–6): AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3.
- chr10:4,871,901–38,783,108, 598 genes, copy number 5–13 (within-gene range 4–13) (broad region; genes not listed).
- chr11:50,170,156–58,578,220, 220 genes, copy number 5 (broad region; genes not listed).
- chr11:66,563,464–70,398,488, 152 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr11:74,235,801–74,311,640, 1 gene, copy number 5 (within-gene range 2–5): P4HA3.
- chr11:74,311,362–75,525,941, 50 genes, copy number 5 (within-gene range 4–5): P4HA3-AS1, PGM2L1, HNRNPA1P40, AP001372.1, AP001085.1, MIR548AL, KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2, POLD3, RANP3, RN7SKP297, CHRDL2, AP001324.3, MIR4696, AP001324.2, AP001324.1, RNF169, XRRA1, AP000560.1, RN7SL239P, AP001992.1, AP001992.2, SPCS2, RNU6-216P, NEU3, AP003175.1, OR2AT2P, NPM1P50, OR2AT4, AP001972.4, SLCO2B1, OR2AT1P, AP001972.3, ZDHHC20P3, TPBGL, ARRB1, AP001972.1, AP001972.5, AP001972.2, MIR326, RPS3, SNORD15A, SNORD15B, KLHL35, GDPD5, AP002815.1.
- chr11:78,016,971–78,079,865, 1 gene, copy number 6 (within-gene range 4–6): NDUFC2-KCTD14.
- chr11:78,063,861–79,441,030, 20 genes, copy number 6 (within-gene range 4–6): THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1.
- chr11:84,887,207–91,993,255, 155 genes, copy number 5–7 (broad region; genes not listed).
- chr11:94,874,052–95,234,391, 18 genes, copy number 6 (within-gene range 3–6): AP002383.2, ST13P11, CWC15, KDM4D, AP002383.1, KDM4E, AP002383.5, AP002383.3, AP002383.4, KDM4F, AP001264.1, SRSF8, ENDOD1, BUD13P1, AP000787.2, AP000787.1, SESN3, AP000787.3.
- chr12:14,169,746–14,255,226, 6 genes, copy number 5: AC092470.1, AC135001.1, AC092112.1, MRPS18CP4, RNU6-491P, GNAI2P1.
- chr12:57,693,955–57,968,399, 25 genes, copy number 7: OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1.
- chr12:58,920,639–60,419,293, 19 genes, copy number 5 (within-gene range 4–5): AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2.
- chr15:89,784,895–90,349,437, 36 genes, copy number 6 (within-gene range 3–6): ANPEP, AP3S2, ARPIN-AP3S2, MIR5094, AC027176.2, MIR5009, RNU6-1111P, ARPIN, RNU7-111P, AC027176.1, AC027176.3, ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3, GABARAPL3.
- chr15:92,393,881–92,468,728, 1 gene, copy number 5 (within-gene range 3–5): ST8SIA2.
- chr15:92,470,233–93,089,204, 24 genes, copy number 5: AC090985.2, C15orf32, LINC00930, AC091544.2, AC091544.4, AC091544.5, FAM174B, AC091544.3, AC091544.7, AC091544.6, HMGN1P38, H2AZ2P1, AC091544.1, AC106028.1, AC106028.3, ASB9P1, AC106028.2, AC106028.4, CHASERR, AC013394.1, CHD2, MIR3175, RGMA, YBX2P2.
- chr16:27,787,528–30,070,457, 137 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr16:80,826,074–81,220,370, 18 genes, copy number 5: ARLNC1, AC009070.1, CMC2, AC092718.7, CENPN, AC092718.2, AC092718.8, AC092718.4, ATMIN, C16orf46, AC092718.3, AC092718.5, AC092718.6, AC092718.1, GCSH, PKD1L2, RNU6-1191P, AC092718.9.
- chr19:31,797,666–45,092,635, 647 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr19:45,091,396–45,178,237, 5 genes, copy number 6 (within-gene range 2–6): PPP1R37, EIF5AP3, AC005757.1, NKPD1, TRAPPC6A.
- chr20:5,482,736–5,890,212, 8 genes, copy number 7 (within-gene range 4–7): LINC00654, LINC01729, RPS18P1, AL109935.1, GPCPD1, EIF4EP1, SHLD1, RNU1-55P.
- chr20:31,257,664–31,723,989, 30 genes, copy number 15: DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON.
- chr22:18,773,665–24,495,074, 398 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,756. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
